Gene-level copy-number profile of specimen HCM-CSHL-0075-C25-85A from HCMI case HCM-CSHL-0075-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.8 years (27,321 days).
Specimen HCM-CSHL-0075-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a77f798c-9a5d-4770-9190-64d52d98ccbf.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0075-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/5ce927de-39a5-4e88-b2cf-1b29ea650f73

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 755; copy number 2: 9,979; copy number 3: 22,778; copy number 4: 16,922; copy number 5: 5,789; copy number 6: 1,972; copy number 7: 78; copy number 8: 32; copy number 13: 24; copy number 14: 11; copy number 16: 30; copy number 17: 5; copy number 19: 5; copy number 25: 5.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 190 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,281,116–147,124,285, 57 genes, copy number 7: RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1, CD160, RNF115, POLR3C, NUDT17, PIAS3, MIR6736, ANKRD35, ITGA10, AC243547.1, PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2, POLR3GL, TXNIP, HJV, AC239799.2, RNVU1-6, LINC01719, NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1, NBPF12, PFN1P8, AC244394.3, AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P.
- chr4:120,684,919–120,922,870, 3 genes, copy number 7: PRDM5, RNU6-550P, SETP12.
- chr7:91,311,368–95,615,132, 80 genes, copy number 13–25 (broad region; genes not listed).
- chr10:65,570,338–65,880,289, 1 gene, copy number 7: LINC01515.
- chr12:4,487,735–5,046,788, 19 genes, copy number 8: C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC005906.2, KCNA1, AC005906.1, KCNA5.
- chr12:33,923,374–34,249,958, 12 genes, copy number 8: RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr16:11,555–14,090, 1 gene, copy number 8: DDX11L10.
- chr17:59,893,046–59,950,574, 1 gene, copy number 7 (within-gene range 3–7): RPS6KB1.
- chr17:59,940,908–60,120,687, 15 genes, copy number 7: AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3.
- chr17:60,124,110–60,125,474, 1 gene, copy number 7: AC025048.5.

Autosomal genes at a single copy (total copy number 1): 733. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
